Gene-level copy-number profile of tumor specimen AP-WPAM-HC from APOLLO case AP-WPAM, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3.
Specimen AP-WPAM-HC: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3791642b-7bc4-48c0-a345-783ca422c8e2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-WPAM-UM (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/e003b212-00c2-4712-b0e4-09e49495dfed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 61; copy number 2: 3,070; copy number 3: 2,087; copy number 4: 20,927; copy number 5: 13,890; copy number 6: 9,179; copy number 7: 3,650; copy number 8: 1,153; copy number 9: 2,579; copy number 10: 674; copy number 11: 716; copy number 12: 152; copy number 13: 133; copy number 16: 7; copy number 18: 15; copy number 20: 1; copy number 21: 3; copy number 25: 36; copy number 27: 18; copy number 28: 25; copy number 31: 6; copy number 38: 2; copy number 53: 6.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,373 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–153,718,347, 438 genes, copy number 9–11 (broad region; genes not listed).
- chr1:154,502,219–155,331,114, 51 genes, copy number 9: TDRD10, UBE2Q1, UBE2Q1-AS1, CHRNB2, AL592078.1, ADAR, KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1.
- chr1:155,946,851–160,828,261, 199 genes, copy number 9 (broad region; genes not listed).
- chr1:161,046,946–248,937,043, 1,745 genes, copy number 9–10 (broad region; genes not listed).
- chr3:11,745–1,404,217, 15 genes, copy number 10–16: LINC01986, AC066595.1, CHL1-AS2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1.
- chr3:18,345,377–18,920,401, 4 genes, copy number 9 (within-gene range 8–9): SATB1, AC144521.1, SATB1-AS1, RAD23BP1.
- chr5:58,198–4,147,429, 92 genes, copy number 9 (broad region; genes not listed).
- chr5:10,971,836–41,968,366, 389 genes, copy number 9–13 (broad region; genes not listed).
- chr5:44,300,247–53,487,134, 56 genes, copy number 9: FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC108114.1, FST.
- chr5:54,313,564–56,481,946, 56 genes, copy number 10: LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO, AC026704.1, DHX29, MTREX, AC020728.1, PLPP1, AC010480.1, MIR5687, RNF138P1, AK4P2, SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948.
- chr8:35,862,123–37,599,858, 25 genes, copy number 9–27: AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4.
- chr8:40,298,697–42,051,994, 31 genes, copy number 11: SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1.
- chr8:79,259,402–113,616,958, 525 genes, copy number 10–12 (broad region; genes not listed).
- chr8:114,791,653–145,066,685, 495 genes, copy number 10–12 (broad region; genes not listed).
- chr10:35,247,025–35,572,669, 1 gene, copy number 10 (within-gene range 7–10): CCNY.
- chr10:35,443,411–36,995,585, 19 genes, copy number 9–10: AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2.
- chr11:67,266,473–70,398,488, 123 genes, copy number 9–10 (within-gene range 4–10) (broad region; genes not listed).
- chr14:31,925,801–38,041,442, 109 genes, copy number 18–53 (within-gene range 5–53) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 51. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
